Somatic mutation profile of tumor specimen TCGA-63-A5MS-01A (aliquot TCGA-63-A5MS-01A-11D-A26M-08) from TCGA case TCGA-63-A5MS, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7445bcc5-2041-4689-9113-15035aab6417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MS-10A (Blood Derived Normal), aliquot TCGA-63-A5MS-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43a0b6bd-3a27-4322-b031-3ff70a87cdb9

The open-access MAF lists 417 somatic variants for this specimen: 325 protein-altering or splice-affecting, 79 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 278, Silent 79, Nonsense Mutation 18, Frame Shift Del 13, Splice Site 7, Intron 5, Splice Region 5, Frame Shift Ins 4, RNA 4, 3'UTR 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.3408-2A>T p.X1136_splice (on ENST00000614293; = p.X1106_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99687492; called by muse, mutect2
- ABCA5 | c.1517A>G p.E506G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101201111; called by muse, mutect2, varscan2
- ABCA5 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101201112; called by muse, mutect2, varscan2
- ABCD2 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429343; called by muse, mutect2
- AC008397.2 | c.1459A>G p.S487G | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99441566; called by muse, mutect2, varscan2
- ACSL6 | c.494T>C p.L165P (on ENST00000379240; = p.L190P on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99733434; called by muse, varscan2
- ADAMTSL3 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99718338; called by muse, mutect2, varscan2
- ADCY7 | c.1593C>T p.D531= | Splice Region (SNP) | VAF 17/146 reads (12%) | catalogued as COSV99575925; called by muse, mutect2, varscan2
- ADGRG4 | c.3160C>A p.L1054I | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99795167; called by muse, mutect2, varscan2
- AGA | c.623-1G>T p.X208_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99219485; called by muse, mutect2, varscan2
- AGA | c.623-2A>C p.X208_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99219488; called by muse, mutect2, varscan2
- AIRE | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764029559, CD1414327, COSV52397876; called by muse, mutect2
- AKR1D1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV99652998; called by muse, mutect2, varscan2
- ALCAM | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.239); catalogued as COSV100064645; called by muse, mutect2
- ALX4 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100241012; called by muse, mutect2, varscan2
- ANK2 | c.841A>T p.M281L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100001096; called by muse, mutect2
- ANKRD52 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99921251; called by muse, varscan2
- AP002748.5 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100567867; called by muse, mutect2
- APOB | c.3675C>A p.H1225Q | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99265149; called by muse, mutect2, varscan2
- APOBEC3B | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.636); catalogued as COSV100213730; called by muse, mutect2
- ARFGEF3 | c.2917A>T p.K973* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99293201; called by muse, mutect2
- ARHGEF18 | c.532G>C p.D178H (on ENST00000359920 / NM_001130955.2; = p.D74H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100149419; called by muse, mutect2
- ASH1L | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs755792596, COSV64207562; called by muse, mutect2, varscan2
- ATP1A3 | c.2552G>C p.R851T (on ENST00000545399 / NM_001256214.2; = p.R838T on NM_152296.5) | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV100132133, COSV100132204; called by muse, mutect2
- ATP4A | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs867542713, COSV52867347; called by muse, mutect2
- ATP7B | c.3353G>T p.R1118L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as CD054307, COSV99666330, COSV99666506; called by muse, mutect2, varscan2
- AUTS2 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100716254; called by muse, mutect2, varscan2
- B3GALNT1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs766473939, COSV100251993; called by muse, mutect2
- BCL9 | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV99324943; called by muse, mutect2, varscan2
- BDP1 | c.6594G>T p.E2198D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV100702969; called by muse, mutect2, varscan2
- C10orf62 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101035256; called by muse, mutect2
- C1S | c.1309_1310del p.R437Dfs*10 | Frame Shift Del (DEL) | VAF 12/125 reads (10%) | catalogued as rs1391790248; called by pindel, varscan2
- C9orf153 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV100188642; called by muse, mutect2, varscan2
- C9orf43 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 17/199 reads (9%) | catalogued as COSV55912906; called by muse, mutect2
- CA10 | c.750G>C p.W250C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99562571; called by muse, mutect2, varscan2
- CATSPERE | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100835095; called by muse, mutect2, varscan2
- CCDC181 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63157047; called by muse, mutect2
- CCDC54 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV99660181; called by muse, mutect2, varscan2
- CCR1 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99946685; called by muse, mutect2, varscan2
- CD22 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV99323113; called by muse, mutect2
- CD226 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115312833; called by muse, mutect2, varscan2
- CD33 | c.327G>C p.R109S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as rs959973986, COSV99220332; called by muse, mutect2
- CD37 | c.69C>T p.F23= | Splice Region (SNP) | VAF 29/253 reads (11%) | catalogued as rs372774796; called by muse, mutect2, varscan2
- CD5L | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100941039; called by muse, mutect2, varscan2
- CDH8 | c.204G>T p.M68I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100181006; called by muse, mutect2, varscan2
- CDKN2A | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV58686555, COSV58721453; called by muse, mutect2, varscan2
- CELA2B | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100657530; called by muse, mutect2, varscan2
- CEP43 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100835601; called by muse, mutect2, varscan2
- CFAP44 | c.1568T>C p.M523T | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs766825874, COSV55617435; called by muse, mutect2
- CHD5 | c.2504T>A p.I835N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV99313363; called by muse, mutect2, varscan2
- CHIA | c.32T>A p.V11D | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100588654; called by muse, mutect2, varscan2
- CHRNA4 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100937402; called by muse, mutect2
- CLSPN | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99230725; called by muse, mutect2
- CLVS2 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV99252542; called by muse, mutect2, varscan2
- CMSS1 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs756587102, COSV101375564; called by muse, mutect2, varscan2
- CNGA1 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV100652207; called by muse, mutect2
- COL22A1 | c.4798G>T p.G1600C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57339737, COSV57350358; called by muse, mutect2, varscan2
- COL23A1 | c.1152C>T p.G384= | Splice Region (SNP) | VAF 9/95 reads (9%) | catalogued as rs779182662, COSV101178573; called by muse, mutect2
- COL3A1 | c.95G>T p.C32F | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482884; called by muse, mutect2
- COL3A1 | c.2662-1G>C p.X888_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100482886; called by muse, mutect2
- COL4A4 | c.4531G>C p.G1511R | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100306662, COSV100306804; called by muse, mutect2, varscan2
- CPNE5 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs749739328, COSV99782697; called by muse, mutect2, varscan2
- CPS1 | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as CX114427, COSV99242770; called by muse, mutect2, varscan2
- CRYGC | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99965292; called by muse, mutect2
- CTNNA2 | c.390G>C p.L130F | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100783437; called by muse, mutect2, varscan2
- CYP2C18 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99608474; called by muse, mutect2
- DBX1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99910182; called by muse, mutect2, varscan2
- DGKD | c.547G>A p.A183T (on ENST00000264057 / NM_152879.3; = p.A139T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV99896115; called by muse, mutect2
- DLG5 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100967421; called by muse, mutect2, varscan2
- DMBT1 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 33/591 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778906988, COSV100352757; called by muse, mutect2
- DMRTA1 | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100364744; called by muse, mutect2, varscan2
- DNAH8 | c.5769A>C p.K1923N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544591; called by muse, mutect2, varscan2
- DNAH9 | c.2100G>C p.L700= | Splice Region (SNP) | VAF 17/151 reads (11%) | catalogued as COSV99305426; called by muse, mutect2
- DNAJC10 | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51144800; called by muse, mutect2
- DNM2 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV100117114; called by muse, mutect2, varscan2
- DOCK10 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99289082; called by muse, mutect2, varscan2
- DPH2 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as rs755058688, COSV99356410; called by muse, mutect2, varscan2
- DPH2 | c.1121C>G p.P374R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.798); catalogued as COSV99356412; called by muse, mutect2, varscan2
- DPPA4 | c.179-1G>T p.X60_splice | Splice Site (SNP) | VAF 10/123 reads (8%) | catalogued as COSV100169385; called by muse, mutect2
- DTX1 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99986313; called by muse, mutect2, varscan2
- EBNA1BP2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99355914; called by muse, mutect2, varscan2
- EDIL3 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99675941; called by muse, mutect2
- EFHB | c.2390G>T p.W797L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV99859461, COSV99860046; called by muse, mutect2, varscan2
- EFNB2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99808686; called by muse, mutect2, varscan2
- EPB41L3 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548823; called by muse, mutect2, varscan2
- EPHA3 | c.2699A>T p.N900I | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as COSV100344648, COSV60715214; called by muse, mutect2
- EPHX2 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100994563; called by mutect2, varscan2
- ESPL1 | c.1786C>G p.R596G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV57760936, COSV99229212; called by muse, mutect2
- FAM135B | c.3049G>T p.A1017S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99422721; called by muse, mutect2
- FAM135B | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52713114, COSV99422724; called by muse, mutect2, varscan2
- FAM13C | c.1533-1G>T p.X511_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99513634; called by muse, mutect2
- FAM193A | c.3140A>T p.Q1047L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV100218992; called by muse, mutect2, varscan2
- FAU | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs764064650, COSV99658062; called by muse, mutect2
- FBH1 | c.760C>T p.P254S (on ENST00000362091 / NM_178150.3; = p.P305S on NM_032807.4) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62983068; called by muse, mutect2
- FBLIM1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs772780243, COSV100181691; called by muse, mutect2, varscan2
- FBXW8 | c.86G>T p.R29M (on ENST00000309909; = p.R67M on NM_012174.1) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV99997631; called by muse, mutect2
- FCGBP | c.11701C>G p.Q3901E | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs551816320; called by muse, mutect2
- FIGN | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV100292198; called by muse, mutect2
- FN1 | c.6753C>A p.C2251* (on ENST00000359671 / NM_001365524.2; = p.C2220* on NM_002026.4) | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100116911; called by muse, mutect2
- FOXD4 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100070822; called by muse, mutect2
- FRMD4B | c.2699G>T p.R900L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs533947293, COSV68329960; called by muse, mutect2, varscan2
- GAB4 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV101271963; called by muse, mutect2, varscan2
- GABRB3 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.53); catalogued as COSV100159371; called by muse, mutect2
- GBX1 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV52546950, COSV99880859; called by muse, mutect2
- GDF3 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs145849916, COSV61712909; called by muse, mutect2, varscan2
- GPS2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 13/136 reads (10%) | catalogued as COSV100222891; called by muse, mutect2
- GSTA2 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101534041, COSV101534068; called by muse, mutect2
- GTDC1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV99600128; called by muse, mutect2, varscan2
- GTF3C1 | c.5272G>C p.D1758H | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100649310; called by muse, mutect2
- H3C2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52518019, COSV52519999; called by muse, mutect2
- HEATR3 | c.1546A>G p.S516G | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99589872; called by muse, varscan2
- HECTD4 | c.7553G>T p.G2518V | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101107311; called by muse, mutect2, varscan2
- HERC1 | c.5188C>G p.Q1730E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.9); catalogued as COSV71247608; called by muse, mutect2
- HERC1 | c.4971C>G p.I1657M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101496513; called by muse, mutect2, varscan2
- HES1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV99220391; called by muse, mutect2, varscan2
- HEXD | c.1082C>T p.P361L (on ENST00000327949 / NM_001369487.1; = p.L391= on NM_173620.3) | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100027695, COSV60063244; called by muse, mutect2
- HMX2 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100378736; called by muse, mutect2
- HOOK3 | c.2046A>T p.E682D | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100295373; called by muse, mutect2, varscan2
- HOXB5 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV99494462; called by muse, mutect2, varscan2
- HPCAL4 | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV100864770, COSV65716219; called by muse, mutect2, varscan2
- HSP90B1 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100236460; called by muse, mutect2, varscan2
- HSPA2 | c.716G>C p.R239P | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV99904865; called by muse, mutect2, varscan2
- HSPG2 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV65974516; called by muse, mutect2, varscan2
- HTT | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs894672916, COSV61863876; called by muse, mutect2
- IL20RB | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100291044; called by muse, mutect2, varscan2
- IMPDH1 | c.344C>T p.T115M (on ENST00000470772 / NM_001142573.2; = p.T201M on NM_000883.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs530528335, CM060290, COSV58315908; called by mutect2, varscan2
- IQGAP2 | c.456G>A p.L152= | Splice Region (SNP) | VAF 8/47 reads (17%) | catalogued as rs1193743303, COSV99167052; called by muse, mutect2, varscan2
- IQGAP3 | c.2657G>T p.R886L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100752124; called by muse, mutect2, varscan2
- JMJD1C | c.3538A>G p.R1180G | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1421206042, COSV100550443; called by muse, mutect2
- KCNH4 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99237070, COSV99237647; called by muse, mutect2, varscan2
- KIF27 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.674); catalogued as COSV99926915; called by muse, mutect2, varscan2
- KMT5B | c.2626A>G p.R876G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430129; called by muse, mutect2, varscan2
- LCE1D | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 18/165 reads (11%) | PolyPhen benign (0.007); catalogued as COSV100405877; called by muse, mutect2, varscan2
- LDB3 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as COSV99555044; called by muse, mutect2, varscan2
- LGALS14 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.11); catalogued as COSV100648422; called by muse, mutect2
- LILRA1 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV99251866; called by muse, mutect2
- LMBR1L | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99918712; called by muse, mutect2, varscan2
- LNPEP | c.2911A>T p.T971S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV99183520; called by muse, mutect2, varscan2
- LRP1B | c.3094G>T p.G1032W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101255702; called by muse, mutect2, varscan2
- LRP2 | c.5737C>G p.L1913V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs151079759, COSV55552253; called by muse, mutect2, varscan2
- LRRC41 | c.1667G>C p.R556P | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.839); catalogued as COSV100586285; called by muse, mutect2, varscan2
- LRRC7 | c.3477C>A p.S1159R (on ENST00000651989 / NM_001370785.2; = p.S1126R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV50443897, COSV99226586; called by muse, mutect2, varscan2
- LRRK2 | c.2770C>A p.R924S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1193372549, COSV100109937; called by muse, mutect2
- LTBP1 | c.5089G>T p.V1697L (on ENST00000404816 / NM_206943.4; = p.V1371L on NM_000627.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs770536450, COSV55385331, COSV99698140; called by muse, mutect2, varscan2
- LYG1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100415841; called by muse, mutect2, varscan2
- MATN4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | PolyPhen possibly damaging (0.891); catalogued as COSV100636981; called by muse, mutect2, varscan2
- MCM10 | c.2385G>C p.E795D (on ENST00000484800 / NM_182751.3; = p.E794D on NM_018518.5) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.048); catalogued as COSV101098074; called by muse, mutect2
- MCM4 | c.2306T>A p.L769Q | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100031452; called by muse, mutect2
- MDGA2 | c.1540A>C p.T514P (on ENST00000399232 / NM_001113498.2; = p.T216P on NM_182830.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100636933, COSV62091447; called by muse, mutect2
- MED23 | c.2374C>T p.L792F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100644917; called by muse, mutect2, varscan2
- MFSD10 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV99296344; called by muse, mutect2, varscan2
- MKI67 | c.4685T>C p.L1562P | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV100896431; called by muse, mutect2
- MKI67 | c.2655G>C p.Q885H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV100896434; called by muse, mutect2, varscan2
- MLLT3 | c.678C>G p.N226K | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV100580899; called by muse, varscan2
- MUC16 | c.18598A>T p.M6200L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV101199526; called by muse, mutect2
- MUSK | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV51892385; called by muse, mutect2, varscan2
- MYBPC1 | c.354G>C p.R118S (on ENST00000550270 / NM_206820.2; = p.R143S on NM_002465.4) | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.57); catalogued as COSV100637922; called by muse, mutect2, varscan2
- MYCT1 | c.487A>T p.R163* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100924058; called by mutect2, varscan2
- MYLK4 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV99193763; called by muse, mutect2, varscan2
- MYO3A | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779362; called by muse, mutect2, varscan2
- NAB2 | c.112C>G p.R38G | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV100272642; called by muse, mutect2
- NCAPD3 | c.2125C>A p.H709N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV101599349; called by muse, mutect2
- NCR2 | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100897215; called by muse, mutect2
- NDC80 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV99859582; called by muse, mutect2
- NEK8 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99261779; called by muse, mutect2
- NELL1 | c.1493A>T p.Q498L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100120765; called by muse, mutect2, varscan2
- NES | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100957846; called by muse, mutect2, varscan2
- NLGN1 | c.1514A>T p.H505L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100849215; called by muse, mutect2, varscan2
- NOA1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99950496; called by muse, mutect2
- NPHP1 | c.2195T>A p.V732E (on ENST00000393272 / NM_207181.4; = p.V733E on NM_000272.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV100337982; called by muse, mutect2
- NPY1R | c.1070C>A p.T357K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713603, COSV99648681; called by muse, mutect2, varscan2
- NR0B2 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99574986; called by muse, mutect2, varscan2
- NSFL1C | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99401319; called by muse, mutect2
- NSUN2 | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99243109; called by muse, mutect2, varscan2
- NUFIP1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100997992; called by muse, mutect2, varscan2
- NUP205 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99606859; called by muse, mutect2, varscan2
- OGDHL | c.2938C>G p.P980A | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100934277; called by muse, mutect2, varscan2
- OR4A15 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV59033448, COSV59037691; called by muse, mutect2
- OR4C11 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155301, COSV56352135; called by muse, mutect2, varscan2
- OR4D10 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV101597007; called by muse, mutect2
- OR5AK2 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100476005; called by muse, mutect2
- OR5H1 | c.616A>T p.I206F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100641681; called by muse, varscan2
- OR5T3 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100282774; called by muse, mutect2, varscan2
- OR6C1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV65574252; called by muse, mutect2, varscan2
- OR8H3 | c.778T>A p.L260I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100538904; called by muse, mutect2
- OR8J3 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV56880195, COSV56880522; called by muse, mutect2, varscan2
- OR8U1 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV100163873; called by muse, mutect2
- OTOP1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99587605; called by muse, mutect2
- PAPOLG | c.1331G>T p.R444I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99474630; called by muse, mutect2
- PCARE | c.2230C>G p.L744V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV100527482, COSV59053826; called by muse, mutect2, varscan2
- PCDHA4 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100793352, COSV63544118; called by muse, mutect2, varscan2
- PCDHGA2 | c.2156G>T p.W719L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as COSV53918243, COSV99536300; called by muse, mutect2, varscan2
- PCLO | c.13217G>A p.R4406K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.705); catalogued as COSV100431190; called by muse, mutect2
- PCLO | c.13215G>T p.M4405I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.203); catalogued as COSV100431192; called by muse, mutect2
- PCLO | c.5555A>G p.H1852R | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100431198, COSV61640430; called by muse, mutect2, varscan2
- PDE3B | c.896C>G p.S299W | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99962399; called by muse, mutect2
- PEG10 | c.386C>A p.A129D (on ENST00000482108 / NM_001040152.2; = p.A163D on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509889; called by muse, mutect2
- PGAP1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV100698139; called by muse, mutect2
- PGK2 | c.496T>A p.F166I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505439, COSV59165562; called by muse, mutect2, varscan2
- PIBF1 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100411414, COSV58325091; called by muse, mutect2, varscan2
- PIGL | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as rs1368647980, COSV99848565; called by muse, mutect2
- PIGV | c.1083C>G p.S361R | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99314881; called by muse, mutect2
- PKHD1L1 | c.8560C>A p.P2854T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101005996; called by muse, mutect2, varscan2
- PLCH1 | c.1000C>T p.R334W (on ENST00000340059 / NM_001130960.2; = p.R346W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.095); catalogued as rs139032779; called by muse, mutect2
- PLXNB2 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as rs369024095, COSV100834022; called by muse, mutect2, varscan2
- PNPLA7 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs371488928, COSV52995982; called by muse, varscan2
- POLQ | c.6262G>C p.E2088Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99952104; called by muse, mutect2, varscan2
- POLR2B | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108022; called by muse, mutect2, varscan2
- POTEE | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs766329455, COSV100387675; called by muse, mutect2, varscan2
- POU4F2 | c.1134C>G p.I378M | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55583817, COSV99850480; called by muse, mutect2
- PPIP5K1 | c.3838C>G p.Q1280E (on ENST00000396923; = p.Q1255E on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100288534; called by muse, mutect2, varscan2
- PPP2R1A | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100436227; called by muse, mutect2
- PPP3CB | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100646101; called by muse, mutect2, varscan2
- PPP4R3B | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99701815, COSV99702440; called by muse, mutect2
- PREX2 | c.3142G>C p.D1048H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV99906616; called by muse, mutect2, varscan2
- PRKCQ | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99576750; called by muse, mutect2, varscan2
- PRKDC | c.9990G>C p.L3330F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as rs1338247331, COSV100040085; called by muse, mutect2
- PRKN | c.258C>A p.D86E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.061); catalogued as COSV100628624, COSV58226637; called by muse, mutect2, varscan2
- PRR19 | c.82del p.E28Nfs*13 | Frame Shift Del (DEL) | VAF 153/314 reads (49%) | catalogued as COSV100004218; called by mutect2, pindel, varscan2
- PRTG | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs1465870583, COSV101221357; called by muse, mutect2, varscan2
- PSMC4 | c.135+2T>C p.X45_splice | Splice Site (SNP) | VAF 76/166 reads (46%) | catalogued as COSV99338221; called by muse, mutect2, varscan2
- PTGDR | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100035546; called by muse, mutect2
- PTP4A1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV101037831; called by muse, mutect2, varscan2
- R3HDM1 | c.3295C>T p.Q1099* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99926103; called by muse, mutect2
- RAP1A | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV100712727; called by muse, mutect2
- RASGRP1 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100171903; called by muse, mutect2, varscan2
- RBL1 | c.2782G>T p.G928C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60331452; called by muse, mutect2
- REG1B | c.325C>A p.R109S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.416); catalogued as rs539158429, COSV100521352; called by muse, mutect2, varscan2
- REV3L | c.5209G>C p.E1737Q | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV100725124; called by muse, mutect2
- RFX4 | c.916C>T p.R306* (on ENST00000392842 / NM_213594.3; = p.R212* on NM_032491.6) | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV57575496; called by muse, mutect2
- RIMS2 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101344430, COSV101344581; called by muse, mutect2, varscan2
- RIPOR1 | c.3461G>T p.C1154F (on ENST00000379312 / NM_001193522.2; = p.C1150F on NM_024519.4) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242995; called by muse, mutect2
- RNF213 | c.7673C>G p.S2558C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100300368; called by muse, mutect2, varscan2
- RNF213 | c.8105C>G p.S2702* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100300371; called by muse, mutect2
- ROBO4 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV100127418, COSV100127513; called by muse, mutect2, varscan2
- RPS4Y1 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99167434; called by muse, mutect2, varscan2
- RTEL1 | c.2394C>A p.S798R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100542109; called by muse, mutect2, varscan2
- SALL1 | c.3188C>T p.P1063L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.922); catalogued as COSV99173366; called by muse, mutect2, varscan2
- SCFD1 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as COSV100356309; called by muse, mutect2
- SCN2A | c.3353A>G p.N1118S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as COSV99331205; called by muse, mutect2
- SCNN1G | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.689); catalogued as rs778449018, COSV100264142; called by muse, mutect2, varscan2
- SCRIB | c.3837C>A p.S1279R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV100253074; called by muse, mutect2, varscan2
- SEC16B | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV100381501; called by muse, mutect2, varscan2
- SEMA3D | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV99406422; called by muse, mutect2, varscan2
- SH3BP4 | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100749118; called by muse, mutect2, varscan2
- SI | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | catalogued as rs984986056, COSV100015181; called by muse, mutect2
- SIPA1L1 | c.1133A>T p.H378L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100665441; called by muse, mutect2, varscan2
- SLC43A3 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725181; called by muse, mutect2, varscan2
- SLC7A7 | c.425A>T p.Y142F | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591647; called by muse, mutect2
- SLC7A8 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 41/446 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.46); catalogued as COSV100382295; called by muse, mutect2
- SLC8B1 | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs746065889, COSV99176694; called by muse, mutect2, varscan2
- SLC9C1 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as rs566504224, COSV99997775; called by mutect2, varscan2
- SLF2 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99489005; called by muse, mutect2
- SLIT3 | c.793G>C p.A265P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100266945; called by muse, mutect2, varscan2
- SMC4 | c.3145G>C p.D1049H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV100557482, COSV100557592; called by muse, mutect2
- SNRNP48 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100672942; called by muse, mutect2
- SOX11 | c.678C>A p.D226E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1337057292, COSV100431013, COSV58987527; called by muse, mutect2, varscan2
- SPARCL1 | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56806375; called by muse, mutect2
- SPHKAP | c.3537C>G p.S1179R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100764062; called by muse, mutect2, varscan2
- SPHKAP | c.2890A>G p.R964G | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs200606198; called by muse, mutect2, varscan2
- SPIRE1 | c.1657G>C p.V553L (on ENST00000409402 / NM_001128626.2; = p.V539L on NM_020148.3) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV100563581; called by muse, mutect2, varscan2
- SRPRB | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.266); catalogued as COSV101524157, COSV71749135; called by muse, mutect2
- SRRM2 | c.6751C>T p.P2251S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV99241436; called by muse, mutect2, varscan2
- SUSD4 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59556006; called by muse, mutect2, varscan2
- SUZ12 | c.1041A>T p.E347D | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as COSV100496845; called by muse, mutect2
- SYNCRIP | c.1435G>C p.G479R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100784165; called by muse, mutect2, varscan2
- SYNE1 | c.11509G>A p.E3837K (on ENST00000367255 / NM_182961.4; = p.E3822K on NM_033071.3) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.082); catalogued as COSV54976866; called by muse, mutect2, varscan2
- SYNM | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs1567285801, COSV100019227, COSV50444803; called by muse, mutect2
- TAF7 | c.506T>C p.L169S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100514959; called by muse, mutect2, varscan2
- TAS2R3 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99924507; called by muse, mutect2
- TAS2R50 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs769149607, COSV67853239; called by muse, mutect2
- TBC1D22B | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100996779; called by muse, mutect2, varscan2
- TDRD6 | c.1309G>T p.V437L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100287478; called by muse, mutect2, varscan2
- TEC | c.318A>T p.L106F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101202601; called by muse, mutect2, varscan2
- TLR5 | c.2431C>A p.Q811K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100643263; called by muse, mutect2, varscan2
- TMEM171 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99824938; called by muse, mutect2, varscan2
- TMEM184A | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99868124; called by muse, mutect2, varscan2
- TMIGD2 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 24/251 reads (10%) | catalogued as COSV100010125, COSV56668276; called by muse, mutect2
- TMTC2 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100337806; called by muse, mutect2, varscan2
- TNS1 | c.3700C>T p.Q1234* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as rs1479288668, COSV99410470; called by muse, mutect2, varscan2
- TP53 | c.456del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | catalogued as COSV52765928, COSV52978254, COSV53086786; called by mutect2, pindel, varscan2
- TRAF3IP2 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 5/109 reads (5%) | catalogued as COSV100389709; called by muse, mutect2
- TRAF4 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52044354; called by muse, mutect2
- TRHDE | c.1380G>C p.W460C | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670331; called by muse, mutect2, varscan2
- TRIM36 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142340; called by muse, mutect2, varscan2
- TRIM42 | c.1949T>C p.M650T | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145744276; called by muse, mutect2
- TRIP4 | c.1496C>G p.P499R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99974517; called by muse, varscan2
- TSPEAR | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs782130480, COSV100553074; called by muse, mutect2, varscan2
- TTN | c.28964G>A p.R9655Q (on ENST00000591111; = p.R8728Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | PolyPhen possibly damaging (0.905); catalogued as rs752814410, COSV60141316; called by muse, mutect2, varscan2
- TWNK | c.1472A>T p.Q491L | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99272314; called by muse, mutect2
- UBE2O | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100084461; called by muse, mutect2, varscan2
- UBXN4 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV55635669; called by muse, mutect2
- UNC93A | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs773257482, COSV57807942; called by muse, mutect2, varscan2
- USP33 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100657089; called by muse, mutect2, varscan2
- UTP20 | c.116G>T p.S39I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV99881434; called by muse, mutect2, varscan2
- VAV1 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100408934; called by muse, mutect2
- XYLB | c.594C>G p.S198R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99264129; called by muse, mutect2
- Z83844.2 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100379115, COSV60928978; called by muse, mutect2
- ZBED4 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763058326, COSV99351109; called by muse, mutect2
- ZC3H3 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99367716; called by muse, mutect2
- ZDBF2 | c.5806C>G p.Q1936E | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs766753250, COSV100984695; called by muse, mutect2, varscan2
- ZFAT | c.3286G>C p.E1096Q | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV100914487; called by muse, mutect2
- ZNF200 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV101205239, COSV101205311; called by muse, mutect2
- ZNF383 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100776746; called by muse, mutect2, varscan2
- ZNF687 | c.2218G>A p.G740S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV99649583; called by muse, mutect2
- ZNF804B | c.3709C>G p.P1237A | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100303311; called by muse, mutect2, varscan2
- ADAMTS13 | c.1543dup p.E515Gfs*19 | Frame Shift Ins (INS) | VAF 44/207 reads (21%) | called by mutect2, pindel, varscan2
- APOBEC4 | c.817del p.Q273Kfs*23 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by mutect2, pindel, varscan2
- ASB2 | c.281dup p.H95Afs*108 | Frame Shift Ins (INS) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- BICRAL | c.3137C>T p.S1046L | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- COMP | c.1976_1983del p.D659Vfs*40 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- DCST1 | c.1609dup p.M537Nfs*61 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- KALRN | c.495del p.S166Pfs*3 | Frame Shift Del (DEL) | VAF 14/127 reads (11%) | called by mutect2, pindel, varscan2
- KMT2D | c.10319del p.A3440Vfs*11 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- MPHOSPH8 | c.1495_1505del p.E499Lfs*9 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- OTOR | c.227del p.N76Mfs*85 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- PSMB4 | c.244_256del p.R82Afs*23 | Frame Shift Del (DEL) | VAF 52/335 reads (16%) | called by mutect2, pindel, varscan2
- PTPN4 | c.446del p.L149* | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SPIN3 | c.56del p.G19Afs*9 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel
- TMEM200A | c.1053dup p.G352Wfs*70 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- TNPO3 | c.1544T>A p.L515Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2
- TRGV4 | c.90C>G p.I30M | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- WASHC2A | c.2505G>T p.K835N | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZIC1 | c.903del p.C304Afs*16 | Frame Shift Del (DEL) | VAF 24/208 reads (12%) | called by mutect2, varscan2
- ACSM2A | c.666T>C p.S222= (on ENST00000219054; = p.S143= on NM_001308169.2) | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99525155; called by muse, mutect2, varscan2
- AGRN | c.1077C>T p.D359= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101038782; called by muse, mutect2, varscan2
- ALPI | c.723C>T p.S241= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV55016526, COSV99785878; called by muse, mutect2, varscan2
- ALPK3 | c.222G>A p.E74= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99360728; called by muse, mutect2, varscan2
- AP1S1 | c.61C>T p.L21= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1178138285, COSV100522646; called by muse, mutect2, varscan2
- AP4M1 | c.894C>G p.L298= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as rs747839303, COSV100384855; called by muse, mutect2, varscan2
- ASAP1 | c.468G>A p.K156= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100727131; called by muse, mutect2, varscan2
- AUTS2 | c.2556C>T p.S852= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV100716255; called by muse, mutect2, varscan2
- BCL11A | c.831C>T p.P277= (on ENST00000335712 / NM_001365609.1; = p.P311= on NM_018014.4) | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as rs553292995, COSV59635955, COSV59636732; called by muse, mutect2
- CCDC62 | c.414C>G p.L138= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as COSV99456938, COSV99457867; called by muse, mutect2, varscan2
- CELSR2 | c.2934G>C p.L978= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV99603657; called by muse, mutect2, varscan2
- CFAP65 | c.810T>C p.N270= | Silent (SNP) | VAF 76/460 reads (17%) | catalogued as COSV99838308; called by muse, mutect2, varscan2
- CHD9 | c.3333G>T p.R1111= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99529058; called by muse, mutect2
- CIBAR1 | c.426T>C p.H142= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100844659; called by muse, mutect2, varscan2
- CNTN6 | c.633C>A p.P211= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100610523; called by muse, mutect2
- CYB5RL | c.84C>T p.C28= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV99838948; called by muse, mutect2, varscan2
- CYP26B1 | c.744G>A p.E248= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99134469; called by muse, mutect2, varscan2
- DHRS2 | c.336G>A p.G112= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1163383213, COSV99159016; called by muse, varscan2
- DLGAP1 | c.1758C>G p.L586= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV100229771; called by muse, mutect2
- DNAJC30 | c.534G>T p.R178= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV99736529; called by muse, mutect2
- DNMBP | c.1581G>C p.P527= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as COSV100143593; called by muse, mutect2
- DOCK10 | c.4605G>A p.L1535= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as COSV99289075; called by muse, mutect2, varscan2
- EIF2B3 | c.1062T>A p.V354= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100838938; called by muse, mutect2
- ENAM | c.2718C>A p.T906= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV101253057; called by muse, mutect2, varscan2
- ERN2 | c.1669C>T p.L557= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99891325; called by muse, mutect2, varscan2
- FCN1 | c.108G>T p.V36= | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as COSV100878879, COSV65662517; called by muse, mutect2, varscan2
- GPR142 | c.1338G>T p.A446= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100170762, COSV59518942; called by muse, mutect2
- GRIK4 | c.1299G>T p.G433= | Silent (SNP) | VAF 33/258 reads (13%) | catalogued as COSV101483596; called by muse, mutect2, varscan2
- HDAC4 | c.2946C>T p.C982= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs199744642, COSV61863950; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEATR5B | c.1773A>G p.E591= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV99249047; called by muse, mutect2, varscan2
- HEPH | c.2770T>C p.L924= (on ENST00000343002; = p.L657= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1025437887, COSV100294689; called by muse, mutect2, varscan2
- IGHG2 | c.177C>G p.S59= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- IL33 | c.360A>G p.T120= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1365693847, COSV101197881; called by muse, mutect2, varscan2
- KCNC4 | c.1839C>T p.D613= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100873602; called by muse, mutect2
- KCNMB2 | c.39T>C p.Y13= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1194087817, COSV100843915; called by muse, mutect2, varscan2
- LAMC1 | c.316C>T p.L106= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99279426; called by muse, mutect2
- MAN2A2 | c.1695C>G p.L565= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100847840, COSV100847975; called by muse, mutect2, varscan2
- MRGPRX3 | c.783C>A p.S261= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV101283517; called by muse, mutect2, varscan2
- MROH5 | c.216G>A p.L72= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV101435971; called by muse, mutect2, varscan2
- NOS1 | c.3666G>C p.R1222= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100500429; called by muse, mutect2, varscan2
- OR10G9 | c.798C>A p.V266= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as COSV100901580, COSV66686297; called by muse, mutect2
- OR4A47 | c.489G>A p.G163= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV101487061; called by muse, mutect2, varscan2
- OR8H1 | c.402T>A p.I134= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs774799735, COSV100477031; called by muse, mutect2, varscan2
- OR8K3 | c.669A>T p.V223= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100449745, COSV57131953; called by muse, mutect2, varscan2
- OR9Q1 | c.708C>A p.T236= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV100109804; called by muse, mutect2
- PAN3 | c.1272T>C p.Y424= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV99144696; called by muse, mutect2, varscan2
- PARD3B | c.855C>T p.L285= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs769264864, COSV100593162; called by muse, mutect2, varscan2
- PDYN | c.196C>T p.L66= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV99452944; called by muse, mutect2
- PHF24 | c.198G>T p.S66= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as COSV54274002, COSV99646036; called by muse, mutect2, varscan2
- PIGQ | c.2013C>T p.V671= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99216005; called by muse, mutect2
- PITPNM2 | c.738G>A p.E246= | Silent (SNP) | VAF 40/242 reads (17%) | catalogued as COSV99758747; called by muse, mutect2, varscan2
- PLEKHM3 | c.627C>T p.F209= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV101216486; called by muse, mutect2, varscan2
- PRNP | c.306G>C p.P102= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV101057253; called by muse, mutect2, varscan2
- PTPRO | c.1005A>T p.S335= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99840330; called by muse, mutect2, varscan2
- PZP | c.258C>T p.V86= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs1180940362, COSV99737468; called by muse, mutect2, varscan2
- SBF1 | c.801G>T p.V267= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100817678; called by muse, mutect2, varscan2
- SCFD2 | c.1158C>G p.L386= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as COSV101189343, COSV66377127; called by muse, mutect2
- SCGB2B2 | c.165G>A p.L55= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs1016674299, COSV101002825; called by muse, mutect2
- SLC25A4 | c.261C>G p.L87= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV99861232; called by muse, mutect2
- SOAT1 | c.1614T>C p.Y538= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs750469935, COSV100858931; called by muse, mutect2, varscan2
- SRRM2 | c.6660C>G p.L2220= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV99241435; called by muse, mutect2
- TAPBPL | c.387C>T p.L129= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99869223; called by muse, mutect2, varscan2
- TARS3 | c.912C>A p.I304= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100254530; called by muse, mutect2, varscan2
- TBX10 | c.306C>A p.I102= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100039710; called by muse, mutect2, varscan2
- TFDP1 | c.706C>T p.L236= | Silent (SNP) | VAF 404/508 reads (80%) | catalogued as COSV100945815; called by muse, mutect2, varscan2
- TFDP2 | c.480A>G p.S160= (on ENST00000489671 / NM_001178139.2; = p.S99= on NM_006286.5) | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100050825; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2316G>A p.R772= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100835972; called by muse, mutect2, varscan2
- TRIO | c.9189G>T p.T3063= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV100702540; called by muse, mutect2, varscan2
- TSPAN14 | c.327C>T p.A109= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs761571527, COSV100540252, COSV59367105; called by muse, mutect2, varscan2
- TUBA3C | c.952T>C p.L318= | Silent (SNP) | VAF 34/237 reads (14%) | catalogued as rs775231192, COSV68029116; called by muse, mutect2, varscan2
- UNC79 | c.5847T>C p.P1949= (on ENST00000393151 / NM_001346218.2; = p.P1772= on NM_020818.5) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99827350; called by muse, mutect2, varscan2
- UROD | c.519C>T p.T173= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV99870134; called by muse, mutect2
- UTP6 | c.39C>G p.L13= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV99911901; called by muse, mutect2, varscan2
- VMO1 | c.192C>G p.L64= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99564658; called by muse, mutect2, varscan2
- WDR64 | c.2889A>G p.L963= | Silent (SNP) | VAF 87/191 reads (46%) | catalogued as COSV100843741; called by muse, mutect2, varscan2
- ZC3H3 | c.888G>T p.S296= | Silent (SNP) | VAF 34/239 reads (14%) | catalogued as COSV52790686, COSV99367721; called by muse, mutect2, varscan2
- ZFYVE26 | c.3900C>T p.L1300= | Silent (SNP) | VAF 16/261 reads (6%) | catalogued as COSV100720325; called by muse, mutect2
- ZFYVE26 | c.1491C>G p.L497= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV100720327; called by muse, mutect2, varscan2
- ZIM2 | c.1395C>G p.A465= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99688578; called by muse, mutect2, varscan2
- BACE2 | c.312+11051C>A | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- C1orf229 | n.867G>T | RNA (SNP) | VAF 6/17 reads (35%) | catalogued as rs867899626; called by muse, mutect2, varscan2
- C1orf229 | n.866G>T | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, varscan2
- LRRC27 | chr10:132331698 C>A | 5'Flank (SNP) | VAF 22/102 reads (22%) | catalogued as COSV100689754; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85613G>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MARVELD3 | chr16:71640542 G>A | 3'Flank (SNP) | VAF 6/141 reads (4%) | catalogued as COSV99194818; called by muse, mutect2
- MCF2L | c.369-404C>G | Intron (SNP) | VAF 250/323 reads (77%) | catalogued as COSV100982403; called by muse, mutect2, varscan2
- RUBCN | c.*500A>G | 3'UTR (SNP) | VAF 49/209 reads (23%) | catalogued as rs763690879, COSV99583841; called by muse, mutect2, varscan2
- SERPINA13P | n.789A>C | RNA (SNP) | VAF 25/237 reads (11%) | called by muse, mutect2, varscan2
- SKP2 | c.1062-1609G>A | Intron (SNP) | VAF 31/135 reads (23%) | called by muse, mutect2, varscan2
- SNORD115-12 | n.28C>G | RNA (SNP) | VAF 25/413 reads (6%) | called by muse, mutect2
- TMPRSS11F | c.1015+2113T>A | Intron (SNP) | VAF 21/164 reads (13%) | catalogued as COSV100678433; called by muse, mutect2, varscan2
- TRIM10 | c.*224A>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100939696; called by muse, mutect2, varscan2
